Somatic mutation profile of tumor specimen TCGA-ZB-A962-01A (aliquot TCGA-ZB-A962-01A-11D-A428-09) from TCGA case TCGA-ZB-A962, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 64.2 years (23,461 days).
Specimen TCGA-ZB-A962-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5547a76c-441d-4704-ba58-2cb9266db528.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A962-10A (Blood Derived Normal), aliquot TCGA-ZB-A962-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dbe774a-c3e5-4671-83d3-4004ff62c829

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 107/320 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CPD | c.4114G>T p.E1372* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV56713802; called by muse, mutect2
- CRHR1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs774998390; called by muse, mutect2, varscan2
- EXOC3L4 | c.1217C>A p.A406E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV101197698; called by muse, mutect2, varscan2
- FLYWCH1 | c.1271C>T p.T424M (on ENST00000253928 / NM_001308068.2; = p.T423M on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546346078, COSV54144337; called by muse, mutect2, varscan2
- GLIS2 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs377111318; called by muse, mutect2
- NF1 | c.7405G>T p.E2469* (on ENST00000358273 / NM_001042492.3; = p.E2448* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100647981; called by muse, mutect2, varscan2
- PRKAR2B | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747403181; called by muse, mutect2, varscan2
- SLC9A5 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs756005398, COSV55362449; called by muse, mutect2, varscan2
- CATSPERB | c.2934C>G p.N978K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD200R1 | c.284C>T p.T95I (on ENST00000471858 / NM_170780.3; = p.T118I on NM_138806.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2
- DDX5 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- NF1 | c.7404G>T p.M2468I (on ENST00000358273 / NM_001042492.3; = p.M2447I on NM_000267.3) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OTOGL | c.4314G>T p.M1438I (on ENST00000547103; = p.M1429I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKA1 | c.553T>A p.S185T | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2
- SLC47A1 | c.1549_1552del p.S517Ifs*38 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by pindel, varscan2
- SPG7 | c.1672A>G p.K558E (on ENST00000268704; = p.K565E on NM_003119.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.025); called by mutect2, varscan2
- ZIM3 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS16 | c.318C>T p.H106= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs780458361; called by muse, mutect2
- MUC2 | c.3669G>A p.P1223= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs146744772; called by muse, mutect2, varscan2
- NLRP8 | c.555C>T p.H185= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs112109260, COSV52589830; called by muse, mutect2, varscan2
- PDK4 | c.276T>C p.Y92= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- SPATA16 | c.1551A>G p.R517= | Silent (SNP) | VAF 40/102 reads (39%) | called by muse, mutect2, varscan2
- SYNE2 | c.14901G>T p.L4967= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
